Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5K6, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5K6-01A (Primary Tumor).

[page 1 of 2]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LEFT ADRENAL TUMOR:

ADRENOCORTICAL CARCINOMA (8.0 CM IN GREATEST DIMENSION), CONFINED TO THE ADRENAL GLAND. (SEE COMMENT)

Margin of resection, no tumor present.

COMMENT

This large tumor shows diffuse growth pattern with extensive necrosis, and the tumor cells show focal areas of Fuhrman nuclear grade 3. Clear cells compromise less than the 25% of tumor cells. There are 7 mitotic figures in 50 high-power fields. The overall features are consistent with adrenocortical carcinoma. was consulted.

GROSS DESCRIPTION

(A) LEFT ADRENAL TUMOR - A left adrenalectomy, 8.0 x 5.5 x 5.0 cm, weighing 0.15 kg., with attached adipose tissue. There is a separate portion of unremarkable adipose tissue, 2.5 x 2.5 x 1.0 cm.

The adrenal gland is nearly entirely replaced by a well circumscribed encapsulated tumor, 8.0 cm in greatest dimension. The cut surfaces are variegated, yellow, tan and red with friable hemorrhagic areas (approximately 40% of the tumor). The tumor abuts the capsule and adjacent adipose tissue.

There is minimal residual normal adrenal cortex and medulla.

INK CODE: Black - surface of adrenal gland.

SECTION CODE: A1-A3, hemorrhagic, friable areas of tumor with margin; A4, A5, tan firm areas of tumor; A6-A8, yellow areas of tumor with adjacent adipose tissue; A9, A10, tumor with adjacent residual adrenal tissue; A11, A12, representative residual adrenal tissue.

CLINICAL HISTORY

None given.

CONSULTANT(S)

SNOMED CODES

T-83000, M-83703

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

these tests have not been

ICD-O-3
Carcinoma, adrenal cortical
8370/3
Site: Adrenal Gland, cortex
Q74.0
JES 1/20/13

[page 2 of 2]
Page:

Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide comment on immunohistochemical study. The original diagnosis remains unchanged.

Addendum completed by

COMMENT

Immunostain for Ki-67 (a proliferative marker) was performed. About 4221 cells are evaluated using an System, 6.8% of the evaluated cells are positive for Ki-67.

Image Analysis

-----END OF REPORT-----

12/22/12

Source: NCI Genomic Data Commons file bbfc833e-2ab6-4a48-b80e-a5451cd18127 (TCGA-OR-A5K6.CB9B68D7-762B-4828-9479-4ECFE346AB5C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).